Surgical pathology report (de-identified scan), TCGA case TCGA-R6-A6KZ, project TCGA-ESCA (Esophageal Carcinoma), tissue source site MD Anderson Cancer Center, specimen TCGA-R6-A6KZ-01A (Primary Tumor).

[page 1 of 2]
Specimen Date/Time:

***** MODIFIED REPORT - REVIEW ADDENDUM SECTION *****

DIAGNOSIS

- (A) ESOPHAGUS (BIOPSY OF ESOPHAGOGASTRIC JUNCTION TUMOR AT 37 TO 48 CENTIMETERS):
INFILTRATING POORLY DIFFERENTIATED AND MUCINOUS ADENOCARCINOMA WITH SCATTERED SIGNET
RING CELLS AND AREAS OF OVERLYING SQUAMOUS EPITHELIUM.
Villiform columnar-lined mucosa with high-grade columnar epithelial dysplasia/intramucosal adenocarcinoma.
Squamous epithelium with balloon cells and non-specific reactive squamous epithelial changes.
Bacterial colonies.

GROSS DESCRIPTION

- (A) GE JUNCTION TUMOR @ 37 TO 48 CM - Multiple red-tan soft tissue fragments aggregating to 1.0 x 0.3 x 0.2 cm. Entirely submitted in cassette A.

CLINICAL HISTORY

GE junction adenoca mets to liver.

SNOMED CODES

T-56000, T-56350, M-81403, M-54030, M-84803, M-84903

"Some tests reported here may have been developed and performance characteristics determined by specifically cleared or approved by the U.S. Food and Drug Administration."

These tests have not been

Entire report and diagnosis completed by:

Start of ADDENDUM

C&F ICD-O-3
Adenocarcinoma NOS 8140/3
path
Adenocarcinoma w/ mixed subtypes
(mucinous, signet ring cell) 8255/3
Site C&F Distal third of esophagus C15.5
path Gastroesophageal junction C16.0
Cp 6/25/13

[page 2 of 2]
This report is issued to give Immunohistochemistry results. Immunohistochemical staining is performed in our lab on a representative paraffin-embedded section of part A.

MARKER	Clone/Vendor	RESULTS	STAINING	SCORE
HER2 overexpression	AB8	Positive	10 %	1+

10% Invasive tumor cells with complete membrane staining for HER2

Uniformity of staining absent for HER2

Homogeneous, dark circumferential pattern present for HER2

FOOTNOTE

For Her 2: Positive cases are those with uniform, intense and complete membrane staining in greater than 30% of invasive tumor cells (Score 3+). Negative cases are defined as those with no staining (Score 0) or weak, incomplete membrane staining in any proportion of cells (Score 1+). Equivocal or indeterminate cases are those with strong staining in less than or equal to 30% of cells, or complete membrane staining that is either non-uniform or weak in intensity, but with obvious circumferential distribution in at least 10% of tumor cells (Score +2).

Reference Wolff AC, Hammond EH, Swartz JN et al. American Society of Clinical Oncology/College of American Pathologists Guideline Recommendations for Human Epidermal Growth Factor Receptor 2 Testing in Breast Cancer. Arch Pathol Lab Med. 2007;131:18-43.

Entire report and diagnosis completed by:

-----END OF REPORT-----

Criteria	hw 6/19/13	Yes	No

Source: NCI Genomic Data Commons file 7563a9c7-5ecf-47bf-93cd-80ac42c2fd45 (TCGA-R6-A6KZ.EBA518EB-FCA7-4378-9E6B-244A050D4A89.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).